Gene-level copy-number profile of tumor specimen TCGA-N5-A4RS-01A from TCGA case TCGA-N5-A4RS, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mullerian mixed tumor; Tissue or organ of origin: Uterus, NOS; FIGO stage: Stage IB; Age at diagnosis: 65.4 years (23,893 days).
Specimen TCGA-N5-A4RS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCS.d2eb7d8c-b51b-4469-b1e7-7f5520e8b87b.absolute_liftover.gene_level_copy_number.v36.tsv, workflow ABSOLUTE segment calls lifted over to GRCh38 (Affymetrix SNP 6.0); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 3,885 have no estimate.
https://portal.gdc.cancer.gov/files/cf3a24b7-1969-46db-b2c6-39414eb60d1c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 6,286; copy number 2: 40,724; copy number 3: 9,201; copy number 4: 165; copy number 5: 104; copy number 6: 43; copy number 7: 215.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-N5-A4RS-01A-11D-A28Q-01): tumor purity 0.97, ploidy 2.1, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 362 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:184,790,724–185,102,603, 6 genes, copy number 6 (within-gene range 2–6): NIBAN1, RNU7-13P, LINC01633, RNA5SP72, RNF2, FTH1P25.
- chr1:205,657,851–205,943,460, 11 genes, copy number 5: SLC45A3, Metazoa_SRP, NUCKS1, SNORA72, RAB29, AC119673.1, SLC41A1, AC119673.2, PM20D1, SLC26A9, AL713965.1.
- chr2:27,889,941–28,338,901, 1 gene, copy number 5 (within-gene range 3–5): BABAM2.
- chr2:28,134,408–28,664,540, 11 genes, copy number 5: AC096552.1, AC093690.1, RPL23AP34, FLJ31356, FOSL2, AC104695.3, AC104695.2, AC104695.1, PLB1, SNRPGP7, AC074011.1.
- chr2:64,486,353–65,056,168, 19 genes, copy number 5: LINC01805, AC008074.2, AFTPH, MIR4434, RNU6-100P, LINC02579, SERTAD2, AC007365.1, RPS10P9, RN7SL341P, Y_RNA, AC007880.1, LINC01800, LINC02245, RN7SL211P, RPL11P1, SLC1A4, RNU6-548P, LINC02576.
- chr2:66,433,452–66,573,869, 1 gene, copy number 6 (within-gene range 3–6): MEIS1.
- chr2:66,574,030–66,971,462, 6 genes, copy number 6: LINC01798, LINC01797, DNMT3AP1, AC009474.1, LINC01799, LINC01628.
- chr7:66,526,088–66,649,067, 3 genes, copy number 5: AC006001.3, RPL35P5, KCTD7.
- chr7:66,654,538–66,671,523, 1 gene, copy number 5: AC006001.2.
- chr10:46,233,885–46,537,864, 10 genes, copy number 5: ANTXRLP1, ANTXRL, AGAP14P, FAM25BP, AC244230.1, ANXA8L1, AC244230.2, LINC00842, HNRNPA1P33, NPY4R.
- chr10:47,460,162–48,060,016, 22 genes, copy number 5 (within-gene range 2–5): ANXA8, AL591684.3, FAM25G, AL591684.1, AGAP9, AL591684.2, BMS1P2, BX547991.1, DUSP8P1, CTSLP2, LINC02675, SHLD2P3, RN7SL453P, RHEBP2, FO681492.1, AC245041.2, NPY4R2, AC245041.1, FAM25C, AGAP12P, RNA5SP315, BMS1P7.
- chr10:87,396,561–87,435,035, 1 gene, copy number 5: FAM245A.
- chr19:27,638,483–35,813,299, 247 genes, copy number 5–7 (broad region; genes not listed).
- chr20:31,944,337–32,585,074, 23 genes, copy number 5: PDRG1, XKR7, AL031658.2, AL031658.1, RNA5SP481, CCM2L, RNA5SP482, HCK, TM9SF4, AL049539.1, RSL24D1P6, TSPY26P, PLAGL2, POFUT1, MIR1825, AL121897.1, KIF3B, AL121583.1, ASXL1, NOL4L, AL034550.1, AL034550.3, AL034550.2.

Autosomal genes at a single copy (total copy number 1): 6,286. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
